Somatic mutation profile of tumor specimen C3L-01963-01 (aliquot CPT0100320009) from CPTAC case C3L-01963, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 63.8 years (23,301 days).
Specimen C3L-01963-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 567ec52a-0124-45e8-9463-85fe42eff1c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01963-31 (Blood Derived Normal), aliquot CPT0101890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05b94959-0244-42e6-8834-c93f0e9b5706

The open-access MAF lists 95 somatic variants for this specimen: 68 protein-altering or splice-affecting, 12 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 12, Frame Shift Del 10, Intron 7, Nonsense Mutation 4, 3'UTR 3, 5'UTR 3, Splice Site 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 124/363 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764277325, COSV61991615; called by muse, mutect2, varscan2
- CENPJ | c.2671A>G p.I891V | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747765839; called by muse, mutect2, varscan2
- DOP1B | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV67693181; called by muse, mutect2, varscan2
- DUSP19 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100700336; called by muse, mutect2, varscan2
- EFEMP1 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 171/524 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as rs199946928; called by muse, mutect2, varscan2
- EGFR | c.1639A>G p.R547G | Missense Mutation (SNP) | VAF 140/431 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1427028322; called by muse, mutect2, varscan2
- EIF4E | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 173/512 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV55188666; called by muse, mutect2, varscan2
- FMR1 | c.1151del p.A384Efs*38 | Frame Shift Del (DEL) | VAF 139/580 reads (24%) | catalogued as COSV54426522; called by mutect2, pindel, varscan2
- GPR26 | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99501193; called by muse, mutect2, varscan2
- HM13 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59438189; called by muse, mutect2, varscan2
- MARK1 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100857019; called by muse, varscan2
- MRPL45 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as rs767448037; called by muse, mutect2, varscan2
- NPAS4 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 119/346 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60649843, COSV60652063; called by muse, mutect2, varscan2
- PARD3 | c.19T>C p.F7L | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776859625, COSV60762032; called by muse, mutect2, varscan2
- PPP4R3C | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1262182825; called by muse, mutect2
- TONSL | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs756475917, COSV101340109; called by muse, mutect2, varscan2
- TOR1AIP1 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 90/274 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs766817911; called by muse, mutect2, varscan2
- TRIM55 | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1193574347, COSV52546152; called by muse, mutect2, varscan2
- USO1 | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV53708380; called by muse, mutect2, varscan2
- VHL | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 182/343 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56548699; called by muse, mutect2, varscan2
- WDR24 | c.2395G>A p.D799N (on ENST00000248142; = p.D669N on NM_032259.4) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs376665117, COSV50205423; called by muse, mutect2, varscan2
- ZDBF2 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.409); catalogued as rs576431275; called by muse, mutect2, varscan2
- AHCYL1 | c.1210del p.I404Sfs*3 | Frame Shift Del (DEL) | VAF 78/289 reads (27%) | called by mutect2, pindel, varscan2
- AHI1 | c.2743C>A p.L915M | Missense Mutation (SNP) | VAF 103/354 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ALDH9A1 | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, varscan2
- ARFIP2 | c.638T>G p.L213W | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOD1L1 | c.3659del p.E1220Gfs*12 | Frame Shift Del (DEL) | VAF 75/226 reads (33%) | called by mutect2, pindel, varscan2
- CEP170B | c.3896C>T p.A1299V (on ENST00000453495; = p.A1228V on NM_015005.3) | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CHPF | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 78/219 reads (36%) | called by muse, mutect2, varscan2
- CHRNA5 | c.945G>C p.E315D | Missense Mutation (SNP) | VAF 119/356 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLUH | c.3501G>T p.Q1167H (on ENST00000435359; = p.Q1206H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CPEB2 | c.1794del p.Q599Rfs*5 | Frame Shift Del (DEL) | VAF 51/154 reads (33%) | called by mutect2, pindel, varscan2
- CUL4A | c.1945G>A p.E649K (on ENST00000375440 / NM_001008895.4; = p.E549K on NM_003589.3) | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DCAKD | c.316_316+13del p.X106_splice | Splice Site (DEL) | VAF 44/138 reads (32%) | called by mutect2, pindel, varscan2
- DGKZ | c.2577T>C p.S859= (on ENST00000454345 / NM_001105540.2; = p.S671= on NM_003646.4) | Splice Region (SNP) | VAF 66/203 reads (33%) | called by muse, mutect2, varscan2
- DGKZ | c.2578G>T p.V860L (on ENST00000454345 / NM_001105540.2; = p.V672L on NM_003646.4) | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM205A | c.257del p.G86Afs*42 | Frame Shift Del (DEL) | VAF 25/96 reads (26%) | called by mutect2, pindel, varscan2
- FAT2 | c.7280T>G p.F2427C | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRAS1 | c.5296G>A p.G1766R | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- FSIP2 | c.9898C>A p.L3300I | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSL3 | c.302A>G p.H101R | Missense Mutation (SNP) | VAF 209/645 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IQCA1 | c.2011C>G p.P671A | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ITGAV | c.1975_1978del p.V659Rfs*34 | Frame Shift Del (DEL) | VAF 80/244 reads (33%) | called by mutect2, pindel, varscan2
- KIAA0232 | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 93/304 reads (31%) | called by muse, mutect2, varscan2
- LSG1 | c.908A>T p.D303V | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MACF1 | c.18386C>A p.T6129N (on ENST00000372915; = p.T4174N on NM_012090.5) | Missense Mutation (SNP) | VAF 83/288 reads (29%) | called by muse, mutect2, varscan2
- MIB1 | c.379A>C p.I127L | Missense Mutation (SNP) | VAF 107/326 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MSANTD4 | c.320T>A p.L107H | Missense Mutation (SNP) | VAF 110/325 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- MYH6 | c.1681T>C p.S561P | Missense Mutation (SNP) | VAF 156/542 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- NBN | c.2234+2T>C p.X745_splice | Splice Site (SNP) | VAF 79/183 reads (43%) | called by muse, mutect2, varscan2
- NOXO1 | c.1013G>A p.G338D (on ENST00000397280 / NM_172168.3; = p.G332D on NM_144603.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NPAS4 | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 120/345 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUMB | c.1618G>A p.G540S (on ENST00000355058; = p.G529S on NM_003744.5) | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PAG1 | c.1089A>C p.K363N | Missense Mutation (SNP) | VAF 116/238 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PALLD | c.1767C>A p.N589K | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PARP4 | c.3788A>T p.E1263V | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PBRM1 | c.1674T>A p.Y558* | Nonsense Mutation (SNP) | VAF 85/196 reads (43%) | called by muse, mutect2, varscan2
- PCLO | c.2663del p.T888Mfs*20 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel, varscan2
- PGAM2 | c.199del p.L67Sfs*46 | Frame Shift Del (DEL) | VAF 207/906 reads (23%) | called by pindel, varscan2*
- PPP1R12C | c.1186G>T p.G396C | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHOC1 | c.3430G>T p.E1144* | Nonsense Mutation (SNP) | VAF 57/150 reads (38%) | called by muse, mutect2, varscan2
- TMEM101 | c.697T>C p.F233L | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TP53BP1 | c.467_471del p.H156Pfs*4 | Frame Shift Del (DEL) | VAF 77/237 reads (32%) | called by mutect2, pindel, varscan2
- TYRO3 | c.2641_2669del p.Q881Lfs*168 | Frame Shift Del (DEL) | VAF 32/194 reads (16%) | called by mutect2, pindel
- UVRAG | c.586T>G p.L196V | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WDR88 | c.1346C>G p.A449G | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- YLPM1 | c.5786T>G p.I1929S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZZEF1 | c.5570G>A p.G1857E | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADD2 | c.1293C>G p.T431= | Silent (SNP) | VAF 54/151 reads (36%) | called by muse, mutect2, varscan2
- AIRE | c.1596C>T p.A532= | Silent (SNP) | VAF 171/456 reads (38%) | called by muse, mutect2, varscan2
- ANXA4 | c.387C>A p.T129= | Silent (SNP) | VAF 53/200 reads (27%) | called by muse, mutect2, varscan2
- BNIP3L | c.222T>C p.I74= | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- CRHR2 | c.1221G>A p.Q407= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV59267777; called by muse, mutect2, varscan2
- FRAS1 | c.3220C>T p.L1074= | Silent (SNP) | VAF 104/316 reads (33%) | called by muse, mutect2, varscan2
- LRP4 | c.4125C>T p.T1375= | Silent (SNP) | VAF 92/299 reads (31%) | catalogued as rs371098163; called by muse, mutect2, varscan2
- P2RX2 | c.1273T>C p.L425= (on ENST00000343948 / NM_170683.4; = p.L327= on NM_012226.5) | Silent (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- POFUT1 | c.996G>C p.L332= | Silent (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- POU2F1 | c.1374T>C p.T458= (on ENST00000541643 / NM_001365848.1; = p.T481= on NM_002697.4) | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- SAMD14 | c.306T>A p.P102= | Silent (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- TUBA4A | c.741C>A p.A247= | Silent (SNP) | VAF 111/340 reads (33%) | called by muse, mutect2, varscan2
- AL136982.4 | n.336C>A | RNA (SNP) | VAF 186/597 reads (31%) | called by mutect2, varscan2
- AL645922.1 | c.256+705C>T | Intron (SNP) | VAF 41/134 reads (31%) | catalogued as rs766407308; called by muse, mutect2, varscan2
- ATP2B3 | c.3342+4627C>T | Intron (SNP) | VAF 60/195 reads (31%) | called by muse, mutect2, varscan2
- CLK4 | c.162-1063C>T | Intron (SNP) | VAF 59/190 reads (31%) | catalogued as rs1363287176; called by muse, mutect2, varscan2
- CPLANE1 | c.8855+26G>T | Intron (SNP) | VAF 62/255 reads (24%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-3173del | Intron (DEL) | VAF 84/202 reads (42%) | called by pindel, varscan2
- LRATD1 | c.*627T>C | 3'UTR (SNP) | VAF 104/340 reads (31%) | called by muse, mutect2, varscan2
- MBNL1 | c.-1347C>A | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs1221301302; called by mutect2, varscan2
- NAA60 | c.*351G>A | 3'UTR (SNP) | VAF 19/107 reads (18%) | catalogued as rs1029759354; called by muse, mutect2, varscan2
- NDUFA11 | c.*12G>A | 3'UTR (SNP) | VAF 64/364 reads (18%) | catalogued as COSV99399037; called by muse, mutect2, varscan2
- PHB2 | c.711+124T>G | Intron (SNP) | VAF 58/191 reads (30%) | called by muse, mutect2, varscan2
- RIDA | c.-45T>C | 5'UTR (SNP) | VAF 62/138 reads (45%) | catalogued as rs199848393; called by muse, mutect2, varscan2
- SCFD2 | c.1562-35289C>T | Intron (SNP) | VAF 99/317 reads (31%) | called by muse, mutect2
- TDG | c.-1A>G | 5'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- ZNF833P | n.700C>A | RNA (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
